Surgical pathology report (de-identified scan), TCGA case TCGA-EI-6882, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-EI-6882-01A (Primary Tumor).

Department of Cancer Pathology

copy No.

Date: 1

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **Multiple organ resection – segment of the large intestine**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Cancer of the rectosigmoid junction.**

Examination performed on:

Macroscopic description:

A 21 cm length of the large intestine with a 3 cm mesorectum tissue. A cauliflower-shaped tumour sized 5.7 x 5.2 x 1 cm found in the mucosa. The lesion surrounding 90% of the intestine circumference, is removed by 13.5 cm from the proximal line and 2.1 cm from the distal line. Minimum side margin is 3 cm.

Microscopic description:

Adenocarcinoma tubuloripillare partim mucinosum (G3). Infiltratio carcinomatosa tunicae muscularispropriae et telae adiposae mesorecti.

Incision lines free of neoplastic lesions.

Lymphonodulitis reactiva (No XXI).

Histopathological diagnosis:

Adenocarcinoma tubulopapillare partim mucinosum recti. Tubulopapillar and partially mucinous adenocarcinoma of the rectum. (G3, Dukes B, Astler-Coller B2, pT3, pNO, RO).

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 9ce78d4c-8bb5-43c6-9ec3-8cc1fdc05d9d (TCGA-EI-6882.660BCAED-4C60-4A2F-AA60-0F0356FB0CF9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).